FM case AD7430 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/02491366-9ac0-4aa7-93a9-1b9781b901a7

Female, 64.0 years: Carcinoma, NOS (ICD-O-3 8010/3); metastasis biopsied or resected from the pleura. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Metastatic.
